Surgical pathology report (de-identified scan), TCGA case TCGA-WX-AA44, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Yale University, specimen TCGA-WX-AA44-01A (Primary Tumor).

[page 1 of 3]
DEPARTMENT OF
PATHOLOGY

SURGICAL PATHOLOGY REPORT

Clinical History and Impression:
Hepatocellular carcinoma.

Specimen(s) Received:
LEFT LATERAL SEGMENT LIVER

FINAL DIAGNOSIS

1) LIVER, LEFT LATERAL SEGMENT, PARTIALLY HEPATECTOMY:

- HEPATOCELLULAR CARCINOMA, MODERATELY TO POORLY DIFFERENTIATED, ARISING IN A BACKGROUND OF MINIMALLY ACTIVE CIRRHOSIS
- 3.5 CM IN DIAMETER
- NO VASCULAR INVASION IDENTIFIED
- MARGIN OF RESECTION AND VASCULAR MARGIN NEGATIVE FOR CARCINOMA
- NON-NEOPLASTIC LIVER WITH MICRONODULAR CIRRHOSIS, OF INDETERMINATE ETIOLOGY WITH MILD ACTIVITY, SEE NOTE
- PATHOLOGIC STAGE (AJCC 2010, 7TH ED.): pT1NX (AT LEAST STAGE I)
- SEE SYNOPTIC REPORT

NOTE: The uninvolved hepatic parenchyma exhibits architecture distorted by fine fibrotic septa surrounding nodules of regenerative hepatocytes. The septa have a moderately severe lymphocytic infiltrate and there is focal mild interface hepatitis. There is minimal macrovesicular steatosis. Iron stain is negative. DPAS stain shows no evidence of alpha-1-antitrypsin accumulation. The inflammatory infiltrate and the near absence of steatosis are not typical of NAFLD-induced cirrhosis and raise questions regarding the etiology of the cirrhosis.

SYNOPTIC SUMMARY

PROCEDURE: Partial hepatectomy
Minor hepatectomy

ICD-O-3
Carcinoma, hepatocellular NOS 8170/3
Site: Liver C22.0
JMS 5/30/14

[page 2 of 3]
SPECIMEN TYPE: Liver

TUMOR SIZE:

Greatest Dimension: 3.5 cm

TUMOR FOCALITY: Solitary: Left lateral segment

HISTOLOGIC TYPE: Hepatocellular carcinoma

HISTOLOGIC GRADE: GII: Moderately differentiated-poorly

TUMOR EXTENSION: Tumor confined to liver

MARGINS:

Parenchymal Margin: Uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 15 mm

Other Margin: Vascular margin

Uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION

Macroscopic Venous (Large Vessel) Invasion (V): Not identified

Microscopic (Small Vessel) Invasion (L): Not identified

PATHOLOGIC STAGE (pTNM):

TNM Descriptors: r (recurrent)

Primary Tumor (pT): pT1: Solitary tumor without vascular invasion

Regional Lymph Nodes (pN): pNX: Cannot be assessed

Distant Metastasis (pM): Not applicable

ADDITIONAL PATHOLOGIC FINDINGS

Background Liver Disease: Cirrhosis

Steatosis (Grade 1)

CLINICAL HISTORY: Type II Diabetes

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Specimen

Gross Specimen

Gross Description:

Received fresh labeled with the patient's name, "left lateral segment liver" is a 270 g, 15.0 x 10.0 x 4.5 cm segment of liver with a 10.0 x 5.0 cm unremarkable cauterized resection margin with a 0.4 cm segment of unremarkable vascular margin. The smooth capsule exhibits multiple tan-white nodules which measure 1.5 x 1.5 x 0.3 cm in aggregate. Upon sectioning, contiguous with the aforementioned nodule, is a 3.5 x 3.5 x 1.5 cm well delineated nodular lesion coming to within 1.5 cm the black inked resection margin. The remaining parenchyma is tan brown and slightly nodular with the nodules ranging

[page 3 of 3]
from 0.2 cm to 0.5 cm in greatest dimension. Representative sections of the tumor and uninvolved parenchyma are saved for ancillary studies. Representative sections are submitted in 5 cassettes, with the en face vascular margin in cassette one, and the uninvolved parenchyma in cassette 5.

Summary of Stains Performed and Reviewed

	Count
Diastase PAS	1
Prussian Blue (Iron)	1
Reticulum, Gordon	1
Trichrome, Klatskin	1

Summary of Tissue Submitted for Microscopic Examination

Block Detail

	# Blocks	Designation	#	Description
Part 1] LEFT LATERAL SEGMENT LIVER	5	T-C	(1)	Tumor to capsule
		T-C AND VM	(1)	Tumor to capsule and vascular margin
		T-M	(2)	Tumor to margin
		U	(1)	Uninvolved

END OF REPORT

Criteria	lw 2/17/14	Yes	No

Source: NCI Genomic Data Commons file 5e2d6e71-7560-4a1c-acdb-c979e46977ab (TCGA-WX-AA44.759F0B44-92DC-4E47-BA10-7B19C4272485.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).